Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2K, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2K-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

Liver, right lobe, resection: Invasive grade 3 (of 4) cholangiocarcinoma forming a lobulated, firm mass (8.9 x 6.8 x 5.5 cm) located 1.1 cm from the surgical margin. The uninvolved liver parenchyma is unremarkable.
Peritoneum, biopsy: Partially calcified fat necrosis

Gallbladder, cholecystectomy: without diagnostic abnormality.
Lymph node, retrocholedochal, biopsy: A single lymph node is negative for tumor.
Small bowel, fistula tract, biopsy: Fistula tract with associated abscess formation.
Colon, sigmoid, segmental resection: Diverticulosis with multiple (4) diverticula and associated diverticulitis.

ICD-O3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct C22.1
W 3/8/14

Source: NCI Genomic Data Commons file d08122c9-f339-488f-ba98-c9175adb4379 (TCGA-W5-AA2K.C7ECD794-87A2-4210-AA67-EBEA73AE5738.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).